Somatic mutation profile of cancer-model specimen HCM-CSHL-0839-C34-85M (3D Organoid, passage 6; aliquot HCM-CSHL-0839-C34-85M-01D-A85L-36), derived from the metastatic tumor of HCMI case HCM-CSHL-0839-C34, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: GX; Age at diagnosis: 65.3 years (23,837 days).
Specimen HCM-CSHL-0839-C34-85M: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 6.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 75fbc9ea-4fee-4306-a976-6e2f15f1dbe1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0839-C34-10A (Blood Derived Normal), aliquot HCM-CSHL-0839-C34-10A-01D-A85L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d484ba14-33e4-4432-b14d-8927a6ddad08

The open-access MAF lists 233 somatic variants for this specimen: 164 protein-altering or splice-affecting, 56 silent, 13 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 140, Silent 56, Nonsense Mutation 18, Intron 7, 3'UTR 3, Frame Shift Del 3, RNA 1, Splice Site 1, 5'UTR 1, Splice Region 1, Frame Shift Ins 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- C3orf70 | c.17C>T p.S6L | Missense Mutation (SNP) | VAF 148/625 reads (24%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.02); PolyPhen benign (0.003); catalogued as rs757159118, COSV58586480, COSV58587413, COSV58588338; called by muse, mutect2, varscan2
- ETFDH | c.1531G>A p.D511N | Missense Mutation (SNP) | VAF 169/325 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs780768015, CM083497, COSV100306677; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- TP53 | c.394A>G p.K132E | Missense Mutation (SNP) | VAF 185/185 reads (100%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs747342068, CM086989, CM973641, COSV52689323, COSV52708494, COSV52979406, COSV53353999; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- ADCY2 | c.688C>T p.R230W | Missense Mutation (SNP) | VAF 107/417 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100602107; called by muse, mutect2, varscan2
- AFF2 | c.1366G>A p.E456K | Missense Mutation (SNP) | VAF 76/502 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.612); catalogued as COSV53989330; called by muse, mutect2, varscan2
- ANK2 | c.8257G>A p.E2753K | Missense Mutation (SNP) | VAF 174/339 reads (51%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.023); catalogued as COSV100002152; called by muse, mutect2, varscan2
- ARCN1 | c.835G>A p.E279K | Missense Mutation (SNP) | VAF 98/238 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.607); catalogued as COSV50615450; called by muse, mutect2, varscan2
- ARIH2 | c.793C>A p.H265N | Missense Mutation (SNP) | VAF 111/122 reads (91%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV62705820; called by mutect2, varscan2
- ATP6V1C2 | c.1168G>A p.E390K (on ENST00000272238 / NM_001039362.2; = p.E344K on NM_144583.4) | Missense Mutation (SNP) | VAF 124/421 reads (29%) | SIFT tolerated (0.38); PolyPhen benign (0.01); catalogued as rs779590851, COSV55351622; called by muse, mutect2
- BARHL1 | c.641C>T p.S214L | Missense Mutation (SNP) | VAF 166/305 reads (54%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.49); catalogued as rs1240260230; called by muse, mutect2, varscan2
- BASP1 | c.640G>A p.A214T | Missense Mutation (SNP) | VAF 116/442 reads (26%) | SIFT tolerated (0.52); PolyPhen benign (0.036); catalogued as rs529077079, COSV59472808; called by muse, varscan2
- C15orf48 | c.220G>A p.E74K | Missense Mutation (SNP) | VAF 134/278 reads (48%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as COSV100721085; called by muse, mutect2, varscan2
- C20orf144 | c.331G>A p.G111R | Missense Mutation (SNP) | VAF 232/470 reads (49%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.434); catalogued as rs776940228; called by muse, mutect2, varscan2
- C5orf22 | c.1213G>A p.D405N | Missense Mutation (SNP) | VAF 53/221 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV57599158; called by muse, mutect2, varscan2
- CCDC183 | c.454G>C p.E152Q | Missense Mutation (SNP) | VAF 147/327 reads (45%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV100565982, COSV62012082; called by muse, mutect2
- CD1A | c.802G>T p.V268L | Missense Mutation (SNP) | VAF 96/402 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as COSV99078800, COSV99192250; called by mutect2, varscan2
- CHST15 | c.468C>G p.I156M | Missense Mutation (SNP) | VAF 134/512 reads (26%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.735); catalogued as COSV100655388; called by muse, mutect2, varscan2
- CPZ | c.253C>G p.L85V (on ENST00000360986 / NM_001014447.3; = p.L74V on NM_003652.3) | Missense Mutation (SNP) | VAF 268/294 reads (91%) | SIFT tolerated (0.31); PolyPhen benign (0.034); catalogued as rs778908291; called by muse, mutect2, varscan2
- CRTC2 | c.284C>T p.S95F | Missense Mutation (SNP) | VAF 130/524 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.34); catalogued as rs1196155813; called by muse, mutect2, varscan2
- CTNS | c.980C>T p.T327M | Missense Mutation (SNP) | VAF 121/121 reads (100%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.772); catalogued as rs1033304034; called by muse, mutect2, varscan2
- DDX58 | c.821C>T p.S274L | Missense Mutation (SNP) | VAF 115/271 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.328); catalogued as COSV65882606; called by muse, mutect2, varscan2
- DMGDH | c.901C>T p.R301* | Nonsense Mutation (SNP) | VAF 176/388 reads (45%) | catalogued as rs199723565; called by muse, mutect2
- EAF2 | c.505C>G p.L169V | Missense Mutation (SNP) | VAF 83/259 reads (32%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs749611850, COSV56543994; called by muse, mutect2, varscan2
- ERRFI1 | c.224C>T p.P75L | Missense Mutation (SNP) | VAF 112/242 reads (46%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs980250925, COSV66310844, COSV66311405; called by muse, varscan2
- FAM120A | c.2194C>T p.R732W | Missense Mutation (SNP) | VAF 141/298 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs752643954; called by muse, mutect2, varscan2
- GOLPH3 | c.430C>T p.Q144* | Nonsense Mutation (SNP) | VAF 117/429 reads (27%) | catalogued as COSV54059646, COSV54059831; called by muse, mutect2, varscan2
- GPR52 | c.967G>A p.V323I | Missense Mutation (SNP) | VAF 124/413 reads (30%) | SIFT tolerated (0.22); PolyPhen benign (0.005); catalogued as COSV99267936; called by muse, mutect2, varscan2
- GPSM1 | c.1634C>T p.S545L | Missense Mutation (SNP) | VAF 189/340 reads (56%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.928); catalogued as rs782626806, COSV52517439; called by muse, mutect2, varscan2
- HBP1 | c.499C>T p.H167Y | Missense Mutation (SNP) | VAF 314/482 reads (65%) | SIFT tolerated (0.42); PolyPhen benign (0.035); catalogued as rs1486646509; called by muse, mutect2
- HSPD1 | c.541G>C p.E181Q | Missense Mutation (SNP) | VAF 132/261 reads (51%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.697); catalogued as COSV61443427, COSV61446053; called by muse, mutect2, varscan2
- HTR3A | c.1330C>T p.R444C | Missense Mutation (SNP) | VAF 262/468 reads (56%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.773); catalogued as rs377539661; called by muse, varscan2
- IGHV1-69 | c.347C>T p.A116V | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.166); catalogued as rs1231417028; called by muse, varscan2
- KBTBD13 | c.973G>A p.V325M | Missense Mutation (SNP) | VAF 190/449 reads (42%) | SIFT deleterious (0.05); PolyPhen benign (0.127); catalogued as rs534380042; called by muse, mutect2, varscan2
- KLHL3 | c.194G>A p.R65H | Missense Mutation (SNP) | VAF 174/341 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs778670860, COSV59053906; called by muse, mutect2, varscan2
- KMT5B | c.76C>T p.Q26* | Nonsense Mutation (SNP) | VAF 192/467 reads (41%) | catalogued as COSV58564192; called by muse, mutect2, varscan2
- LMBR1 | c.1013C>G p.A338G | Missense Mutation (SNP) | VAF 248/390 reads (64%) | SIFT tolerated (0.13); PolyPhen benign (0.258); catalogued as COSV62219118; called by muse, mutect2, varscan2
- LRRTM4 | c.680G>A p.R227H | Missense Mutation (SNP) | VAF 132/283 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.629); catalogued as rs764914907; called by muse, mutect2, varscan2
- LY75-CD302 | c.5062G>A p.E1688K | Missense Mutation (SNP) | VAF 127/256 reads (50%) | SIFT tolerated (0.51); PolyPhen benign (0.054); catalogued as rs916021125; called by muse, mutect2, varscan2
- LYPLA1 | c.494C>G p.S165C | Missense Mutation (SNP) | VAF 109/260 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.658); catalogued as COSV57606934; called by muse, mutect2, varscan2
- MACF1 | c.359C>G p.S120* | Nonsense Mutation (SNP) | VAF 103/208 reads (50%) | catalogued as COSV57103368; called by muse, mutect2, varscan2
- MAP3K12 | c.2365G>A p.D789N | Missense Mutation (SNP) | VAF 190/688 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.414); catalogued as rs1193076395; called by muse, mutect2, varscan2
- MBOAT1 | c.151C>T p.R51C | Missense Mutation (SNP) | VAF 144/301 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs184491612; called by muse, mutect2, varscan2
- MTCL1 | c.5426G>A p.R1809Q (on ENST00000306329 / NM_001378206.1; = p.R1490Q on NM_015210.4) | Missense Mutation (SNP) | VAF 232/253 reads (92%) | SIFT tolerated (0.2); PolyPhen benign (0.066); catalogued as rs570299046, COSV60404565; called by muse, mutect2, varscan2
- MUC17 | c.5899C>G p.P1967A | Missense Mutation (SNP) | VAF 238/734 reads (32%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.662); catalogued as rs568723888, COSV60295022; called by muse, mutect2, varscan2
- MYEF2 | c.1199G>A p.R400Q | Missense Mutation (SNP) | VAF 136/274 reads (50%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.988); catalogued as rs34619312; called by muse, mutect2, varscan2
- NHP2 | c.34G>A p.E12K | Missense Mutation (SNP) | VAF 159/312 reads (51%) | SIFT tolerated (0.07); PolyPhen benign (0.04); catalogued as rs1296058145; called by muse, varscan2
- NID1 | c.2105G>A p.R702Q | Missense Mutation (SNP) | VAF 103/388 reads (27%) | SIFT tolerated (0.49); PolyPhen benign (0.048); catalogued as rs149309893, COSV51622376; called by muse, mutect2, varscan2
- NLN | c.1743G>C p.L581F | Missense Mutation (SNP) | VAF 151/361 reads (42%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.943); catalogued as COSV101114427; called by muse, mutect2, varscan2
- NRXN3 | c.704C>G p.S235* | Nonsense Mutation (SNP) | VAF 97/205 reads (47%) | catalogued as COSV73586295; called by muse, mutect2, varscan2
- NRXN3 | c.2823C>G p.I941M (on ENST00000335750 / NM_001330195.2; = p.I568M on NM_004796.6) | Missense Mutation (SNP) | VAF 130/279 reads (47%) | SIFT tolerated (1); PolyPhen probably damaging (0.984); catalogued as COSV59730982; called by muse, mutect2, varscan2
- OR4A15 | c.58G>A p.E20K | Missense Mutation (SNP) | VAF 81/389 reads (21%) | SIFT tolerated, low confidence (0.65); PolyPhen benign (0.067); catalogued as COSV59035140; called by muse, mutect2, varscan2
- OTOF | c.1222G>A p.E408K | Missense Mutation (SNP) | VAF 244/405 reads (60%) | SIFT tolerated (0.58); PolyPhen benign (0.272); catalogued as rs747492513, COSV55514081; called by muse, mutect2, varscan2
- OTUD4 | c.1766C>G p.S589C (on ENST00000447906 / NM_001366057.1; = p.S524C on NM_001102653.1) | Missense Mutation (SNP) | VAF 166/355 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.139); catalogued as rs777213342; called by muse, mutect2, varscan2
- PCDH10 | c.1008C>A p.N336K | Missense Mutation (SNP) | VAF 188/359 reads (52%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.719); catalogued as COSV52092488; called by muse, mutect2, varscan2
- PCLO | c.6889G>A p.E2297K | Missense Mutation (SNP) | VAF 289/447 reads (65%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.006); catalogued as COSV61633973, COSV61674490; called by muse, mutect2, varscan2
- PDF | c.418C>T p.R140C | Missense Mutation (SNP) | VAF 224/478 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.58); catalogued as rs373256271; called by muse, varscan2
- PHIP | c.1858C>T p.Q620* | Nonsense Mutation (SNP) | VAF 78/184 reads (42%) | catalogued as COSV99245115; called by muse, mutect2, varscan2
- PLCE1 | c.355C>T p.Q119* | Nonsense Mutation (SNP) | VAF 115/447 reads (26%) | catalogued as COSV53335140; called by muse, mutect2, varscan2
- PSTPIP1 | c.303G>T p.E101D | Missense Mutation (SNP) | VAF 12/326 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as rs1483586815; called by muse, mutect2
- RBM19 | c.861G>C p.Q287H | Missense Mutation (SNP) | VAF 144/527 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.235); catalogued as rs770819586, COSV55693245; called by muse, mutect2, varscan2
- REC8 | c.1565C>T p.S522L | Missense Mutation (SNP) | VAF 118/248 reads (48%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as rs757113882; called by muse, varscan2
- RNASE10 | c.381G>T p.M127I | Missense Mutation (SNP) | VAF 207/404 reads (51%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV60517408; called by muse, mutect2, varscan2
- RTKN | c.148C>T p.R50W (on ENST00000272430 / NM_001015055.2; = p.R37W on NM_033046.2) | Missense Mutation (SNP) | VAF 184/366 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs751247798; called by muse, mutect2, varscan2
- RYR2 | c.14656-1G>C p.X4886_splice | Splice Site (SNP) | VAF 87/184 reads (47%) | catalogued as COSV100769970, COSV63688388; called by muse, mutect2, varscan2
- SALL1 | c.3184G>C p.E1062Q | Missense Mutation (SNP) | VAF 182/378 reads (48%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.994); catalogued as COSV51758759; called by muse, mutect2, varscan2
- SLC25A43 | c.428C>T p.S143L | Missense Mutation (SNP) | VAF 140/526 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.387); catalogued as rs1371544733; called by muse, mutect2, varscan2
- SLC9A9 | c.685G>A p.D229N | Missense Mutation (SNP) | VAF 86/326 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs199542427, COSV57223443; called by muse, mutect2, varscan2
- SNCAIP | c.22G>C p.D8H | Missense Mutation (SNP) | VAF 107/273 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54405893; called by muse, mutect2, varscan2
- STK16 | c.510G>A p.M170I | Missense Mutation (SNP) | VAF 199/403 reads (49%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.49); catalogued as rs751098957, COSV50280426; called by muse, mutect2, varscan2
- SVEP1 | c.6631G>A p.E2211K | Missense Mutation (SNP) | VAF 106/221 reads (48%) | SIFT tolerated (0.28); PolyPhen benign (0.033); catalogued as COSV52845079; called by muse, mutect2, varscan2
- SVOPL | c.1397C>A p.S466* (on ENST00000419765; = p.S314* on NM_174959.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 201/306 reads (66%) | catalogued as COSV55989290; called by muse, mutect2, varscan2
- TCF25 | c.1505A>G p.Y502C | Missense Mutation (SNP) | VAF 140/328 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs775684725; called by muse, mutect2
- TEX13C | c.499G>C p.E167Q | Missense Mutation (SNP) | VAF 168/523 reads (32%) | SIFT tolerated (0.5); PolyPhen benign (0.072); catalogued as COSV101332350; called by muse, mutect2, varscan2
- TNFSF4 | c.484G>A p.D162N | Missense Mutation (SNP) | VAF 173/434 reads (40%) | SIFT tolerated (0.39); PolyPhen benign (0.019); catalogued as COSV99919462; called by muse, mutect2, varscan2
- TP53BP2 | c.1430C>A p.S477Y (on ENST00000343537 / NM_001031685.3; = p.S348Y on NM_005426.2) | Missense Mutation (SNP) | VAF 162/400 reads (41%) | SIFT tolerated (0.34); PolyPhen benign (0.188); catalogued as COSV100636878; called by mutect2, varscan2
- TRIM49 | c.148G>T p.V50F | Missense Mutation (SNP) | VAF 171/541 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.389); catalogued as COSV61670585; called by muse, mutect2, varscan2
- TTI2 | c.205G>T p.E69* | Nonsense Mutation (SNP) | VAF 186/365 reads (51%) | catalogued as COSV62452154; called by muse, mutect2, varscan2
- ZFYVE1 | c.432G>A p.M144I | Missense Mutation (SNP) | VAF 132/331 reads (40%) | SIFT tolerated (0.36); PolyPhen benign (0.006); catalogued as rs1393364820; called by muse, mutect2, varscan2
- ZNF106 | c.4559A>G p.D1520G | Missense Mutation (SNP) | VAF 153/329 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.494); catalogued as rs749557418; called by muse, mutect2, varscan2
- ABCA8 | c.2141G>A p.R714K | Missense Mutation (SNP) | VAF 194/387 reads (50%) | SIFT tolerated (0.12); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- ABCC10 | c.2365G>C p.E789Q (on ENST00000372530 / NM_001198934.2; = p.E761Q on NM_033450.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 201/417 reads (48%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.637); called by muse, mutect2, varscan2
- ACTN4 | c.7G>A p.D3N | Missense Mutation (SNP) | VAF 128/408 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.234); called by muse, varscan2
- ADAM17 | c.714C>G p.Y238* | Nonsense Mutation (SNP) | VAF 291/438 reads (66%) | called by muse, mutect2, varscan2
- ADGRG3 | c.389G>A p.R130K | Missense Mutation (SNP) | VAF 224/415 reads (54%) | SIFT tolerated (0.57); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- APLF | c.976G>C p.E326Q | Missense Mutation (SNP) | VAF 165/323 reads (51%) | SIFT tolerated (0.13); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- ARHGAP27 | c.2207G>A p.G736E (on ENST00000428638 / NM_001282290.1; = p.G395E on NM_199282.3) | Missense Mutation (SNP) | VAF 171/336 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ATAD1 | c.654T>A p.S218R | Missense Mutation (SNP) | VAF 210/328 reads (64%) | SIFT deleterious (0.04); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- ATL3 | c.1209G>C p.K403N | Missense Mutation (SNP) | VAF 378/580 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- ATP2C1 | c.591G>T p.K197N | Missense Mutation (SNP) | VAF 132/408 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by mutect2, varscan2
- BTBD16 | c.985C>A p.L329M | Missense Mutation (SNP) | VAF 124/463 reads (27%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.741); called by muse, mutect2
- BVES | c.695G>C p.R232T | Missense Mutation (SNP) | VAF 80/202 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CCDC149 | c.1423G>T p.E475* (on ENST00000635206 / NM_001330643.2; = p.E464* on NM_173463.5) | Nonsense Mutation (SNP) | VAF 190/206 reads (92%) | called by mutect2, varscan2
- CCDC191 | c.1369G>C p.E457Q | Missense Mutation (SNP) | VAF 163/502 reads (32%) | SIFT tolerated (0.48); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- CCDC39 | c.928G>A p.E310K | Missense Mutation (SNP) | VAF 79/352 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CCER2 | c.159G>C p.Q53H | Missense Mutation (SNP) | VAF 392/593 reads (66%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- CCNL2 | c.757G>A p.E253K | Missense Mutation (SNP) | VAF 138/434 reads (32%) | SIFT tolerated (0.55); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- CD82 | c.478G>A p.D160N | Missense Mutation (SNP) | VAF 147/278 reads (53%) | SIFT tolerated (0.48); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CDH3 | c.727G>A p.D243N | Missense Mutation (SNP) | VAF 44/279 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CDK13 | c.3194C>T p.S1065F | Missense Mutation (SNP) | VAF 9/162 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.048); called by muse, mutect2
- CLDN8 | c.452C>G p.S151* | Nonsense Mutation (SNP) | VAF 20/334 reads (6%) | called by muse, mutect2
- COMMD2 | c.250G>A p.D84N | Missense Mutation (SNP) | VAF 78/281 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.762); called by muse, mutect2, varscan2
- CRACD | c.3401G>A p.G1134E | Missense Mutation (SNP) | VAF 129/143 reads (90%) | SIFT tolerated (0.19); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- CUL4A | c.818G>T p.R273I (on ENST00000375440 / NM_001008895.4; = p.R173I on NM_003589.3) | Missense Mutation (SNP) | VAF 118/119 reads (99%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- DDX23 | c.1077del p.K361Sfs*2 | Frame Shift Del (DEL) | VAF 145/662 reads (22%) | called by mutect2, pindel, varscan2
- DIAPH3 | c.71C>T p.S24L | Missense Mutation (SNP) | VAF 198/224 reads (88%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.14); called by muse, mutect2, varscan2
- DLC1 | c.234G>A p.M78I | Missense Mutation (SNP) | VAF 185/396 reads (47%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- DNAH17 | c.8768G>C p.R2923T | Missense Mutation (SNP) | VAF 226/438 reads (52%) | SIFT deleterious (0.03); PolyPhen benign (0.245); called by muse, mutect2, varscan2
- DOCK9 | c.3358G>T p.E1120* (on ENST00000376460 / NM_001366676.2; = p.E1121* on NM_015296.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 155/179 reads (87%) | called by muse, mutect2, varscan2
- DUSP16 | c.1212C>G p.I404M | Missense Mutation (SNP) | VAF 190/192 reads (99%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- EEF1A1 | c.1162G>A p.E388K | Missense Mutation (SNP) | VAF 93/247 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ELL3 | c.817C>G p.Q273E | Missense Mutation (SNP) | VAF 108/244 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- EPB41L4B | c.2299C>T p.L767= | Splice Region (SNP) | VAF 126/249 reads (51%) | called by muse, mutect2, varscan2
- EPHA1 | c.488C>T p.S163F | Missense Mutation (SNP) | VAF 384/566 reads (68%) | SIFT deleterious (0.05); PolyPhen benign (0.185); called by muse, mutect2, varscan2
- FAM149B1 | c.223A>T p.S75C | Missense Mutation (SNP) | VAF 128/385 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); called by muse, mutect2, varscan2
- FOXN3 | c.676C>G p.Q226E | Missense Mutation (SNP) | VAF 16/373 reads (4%) | SIFT tolerated (0.12); PolyPhen benign (0.04); called by muse, mutect2
- GCM1 | c.943A>C p.N315H | Missense Mutation (SNP) | VAF 199/349 reads (57%) | SIFT deleterious (0.02); PolyPhen benign (0.204); called by muse, mutect2, varscan2
- GGNBP2 | c.295C>T p.L99F | Missense Mutation (SNP) | VAF 213/453 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- GIT2 | c.1231A>G p.N411D (on ENST00000355312 / NM_057169.5; = p.N413D on NM_014776.5) | Missense Mutation (SNP) | VAF 398/398 reads (100%) | SIFT tolerated (0.3); PolyPhen benign (0); called by muse, mutect2, varscan2
- GRAMD1B | c.842C>A p.S281Y | Missense Mutation (SNP) | VAF 263/447 reads (59%) | SIFT tolerated (0.37); PolyPhen benign (0.271); called by muse, mutect2, varscan2
- GUCY1A2 | c.1856C>T p.S619L | Missense Mutation (SNP) | VAF 117/268 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.301); called by muse, mutect2, varscan2
- INTS5 | c.1640C>G p.S547C | Missense Mutation (SNP) | VAF 17/479 reads (4%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.85); called by muse, mutect2
- KIAA0319 | c.734G>T p.G245V | Missense Mutation (SNP) | VAF 119/257 reads (46%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.454); called by muse, mutect2, varscan2
- LMTK2 | c.2076G>C p.K692N | Missense Mutation (SNP) | VAF 334/503 reads (66%) | SIFT tolerated (0.37); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- LPGAT1 | c.818G>A p.G273E | Missense Mutation (SNP) | VAF 134/316 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- MAP3K12 | c.2521G>A p.E841K | Missense Mutation (SNP) | VAF 150/584 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- MAP3K13 | c.657C>G p.F219L | Missense Mutation (SNP) | VAF 190/376 reads (51%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.759); called by muse, mutect2, varscan2
- MUC12 | c.12890C>G p.S4297* (on ENST00000379442; = p.S4154* on NM_001164462.1) | Nonsense Mutation (SNP) | VAF 158/160 reads (99%) | called by mutect2, varscan2
- NAPRT | c.1508G>C p.R503P | Missense Mutation (SNP) | VAF 242/267 reads (91%) | SIFT tolerated (0.27); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- NEURL1B | c.109G>A p.E37K | Missense Mutation (SNP) | VAF 198/517 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- NIM1K | c.1112T>A p.I371N | Missense Mutation (SNP) | VAF 203/588 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.73); called by muse, mutect2, varscan2
- NIPBL | c.674G>T p.G225V | Missense Mutation (SNP) | VAF 303/474 reads (64%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.522); called by muse, mutect2, varscan2
- NME7 | c.676G>A p.G226R | Missense Mutation (SNP) | VAF 156/420 reads (37%) | SIFT tolerated (0.28); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- NPEPPS | c.74G>A p.R25H | Missense Mutation (SNP) | VAF 31/296 reads (10%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0); called by muse, varscan2
- NRXN1 | c.149G>A p.C50Y | Missense Mutation (SNP) | VAF 230/665 reads (35%) | SIFT tolerated (0.12); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- OR56A5 | c.572C>G p.S191C | Missense Mutation (SNP) | VAF 145/248 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PACS2 | c.11G>A p.R4Q | Missense Mutation (SNP) | VAF 68/283 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PKD1 | c.7067_7068dup p.L2357Cfs*2 | Frame Shift Ins (INS) | VAF 95/249 reads (38%) | called by mutect2, pindel, varscan2
- PKDCC | c.91G>C p.E31Q | Missense Mutation (SNP) | VAF 239/642 reads (37%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.113); called by muse, mutect2, varscan2
- POM121 | c.2279_2289del p.L760Hfs*13 (on ENST00000434423; = p.L495Hfs*13 on NM_172020.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 432/1140 reads (38%) | called by mutect2, pindel, varscan2
- PUM2 | c.2834G>A p.G945E | Missense Mutation (SNP) | VAF 302/485 reads (62%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); called by muse, mutect2, varscan2
- RFX5 | c.1244G>A p.R415K | Missense Mutation (SNP) | VAF 278/692 reads (40%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- RIPK2 | c.160C>T p.P54S | Missense Mutation (SNP) | VAF 125/259 reads (48%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.49); called by muse, mutect2, varscan2
- RLN1 | c.169C>G p.L57V | Missense Mutation (SNP) | VAF 129/142 reads (91%) | SIFT tolerated (0.14); PolyPhen benign (0.258); called by muse, mutect2, varscan2
- RNF216 | c.721G>A p.E241K (on ENST00000425013 / NM_207116.3; = p.E298K on NM_207111.4) | Missense Mutation (SNP) | VAF 20/234 reads (9%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.737); called by muse, mutect2
- RPE65 | c.993G>A p.W331* | Nonsense Mutation (SNP) | VAF 117/315 reads (37%) | called by muse, mutect2, varscan2
- RYR2 | c.271G>T p.G91W | Missense Mutation (SNP) | VAF 53/231 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by mutect2, varscan2
- SCGB1A1 | c.64G>T p.E22* | Nonsense Mutation (SNP) | VAF 82/165 reads (50%) | called by muse, mutect2, varscan2
- SELENOK | c.13T>G p.S5A | Missense Mutation (SNP) | VAF 131/131 reads (100%) | SIFT tolerated (0.15); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- SHTN1 | c.1788_1800del p.A597Qfs*23 | Frame Shift Del (DEL) | VAF 165/620 reads (27%) | called by mutect2, pindel, varscan2
- SLX1A | c.583G>A p.D195N | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0.052); called by mutect2, varscan2
- SORCS1 | c.91G>A p.V31I | Missense Mutation (SNP) | VAF 224/734 reads (31%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); called by muse, mutect2, varscan2
- ST7 | c.7G>T p.E3* | Nonsense Mutation (SNP) | VAF 195/294 reads (66%) | called by muse, mutect2, varscan2
- SVEP1 | c.10006G>C p.E3336Q | Missense Mutation (SNP) | VAF 213/395 reads (54%) | SIFT tolerated (0.51); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- TAF4 | c.1873C>T p.Q625* | Nonsense Mutation (SNP) | VAF 108/243 reads (44%) | called by muse, mutect2, varscan2
- TFAP2A | c.255C>A p.N85K (on ENST00000482890; = p.N77K on NM_001032280.3) | Missense Mutation (SNP) | VAF 128/266 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- TOR1AIP1 | c.1495G>A p.E499K | Missense Mutation (SNP) | VAF 141/412 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TTC16 | c.291C>A p.F97L | Missense Mutation (SNP) | VAF 12/247 reads (5%) | SIFT tolerated (0.2); PolyPhen benign (0.027); called by muse, mutect2
- UBXN1 | c.374G>A p.R125K | Missense Mutation (SNP) | VAF 228/490 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.202); called by muse, mutect2, varscan2
- UQCC1 | c.649G>A p.E217K | Missense Mutation (SNP) | VAF 83/161 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); called by muse, mutect2, varscan2
- ZBED4 | c.1954C>T p.H652Y | Missense Mutation (SNP) | VAF 182/353 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.622); called by muse, mutect2, varscan2
- ZDHHC11B | c.792G>T p.K264N | Missense Mutation (SNP) | VAF 84/507 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.18); called by muse, mutect2, varscan2
- ZFHX4 | c.1215A>C p.E405D | Missense Mutation (SNP) | VAF 174/361 reads (48%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- ZFP92 | c.572G>T p.R191L | Missense Mutation (SNP) | VAF 583/1261 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.136); called by muse, varscan2
- ZNF711 | c.1885C>T p.H629Y | Missense Mutation (SNP) | VAF 28/626 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.101); called by muse, mutect2
- AATK | c.1557C>T p.L519= (on ENST00000326724 / NM_001080395.3; = p.L416= on NM_004920.2) | Silent (SNP) | VAF 107/1131 reads (9%) | called by muse, mutect2
- ADAMTS12 | c.1248G>A p.P416= | Silent (SNP) | VAF 137/458 reads (30%) | catalogued as rs768460255, COSV61255591; called by muse, varscan2
- AHNAK | c.14091C>T p.I4697= | Silent (SNP) | VAF 233/502 reads (46%) | catalogued as rs375130667; called by muse, mutect2, varscan2
- ARHGEF4 | c.790C>T p.L264= | Silent (SNP) | VAF 229/483 reads (47%) | called by muse, mutect2, varscan2
- ATAT1 | c.66G>T p.L22= | Silent (SNP) | VAF 91/468 reads (19%) | catalogued as COSV52541159; called by muse, mutect2, varscan2
- CA14 | c.288G>C p.L96= | Silent (SNP) | VAF 201/511 reads (39%) | called by muse, mutect2, varscan2
- CCNB1IP1 | c.408G>A p.L136= | Silent (SNP) | VAF 165/353 reads (47%) | called by muse, mutect2, varscan2
- CDH10 | c.1842G>A p.L614= | Silent (SNP) | VAF 94/375 reads (25%) | catalogued as COSV100050337, COSV52581148; called by muse, mutect2, varscan2
- CFAP47 | c.3726C>T p.F1242= | Silent (SNP) | VAF 42/267 reads (16%) | called by muse, mutect2, varscan2
- CYP27C1 | c.519C>T p.N173= | Silent (SNP) | VAF 145/287 reads (51%) | catalogued as rs372803782; called by muse, mutect2, varscan2
- CYP4F8 | c.63C>T p.L21= | Silent (SNP) | VAF 288/289 reads (100%) | called by muse, mutect2, varscan2
- DGKZ | c.2484G>A p.P828= (on ENST00000454345 / NM_001105540.2; = p.P640= on NM_003646.4) | Silent (SNP) | VAF 100/241 reads (41%) | catalogued as rs376231459; called by muse, mutect2, varscan2
- DNAH5 | c.10908C>T p.H3636= | Silent (SNP) | VAF 163/483 reads (34%) | called by muse, mutect2, varscan2
- DPEP1 | c.420G>A p.V140= | Silent (SNP) | VAF 224/476 reads (47%) | called by muse, mutect2, varscan2
- DTX1 | c.1824C>G p.L608= | Silent (SNP) | VAF 72/464 reads (16%) | called by muse, mutect2, varscan2
- DUSP18 | c.501C>T p.V167= | Silent (SNP) | VAF 16/358 reads (4%) | called by muse, mutect2
- ECI2 | c.1184G>A p.*395= (on ENST00000380118 / NM_206836.3; = p.*365= on NM_006117.2) | Silent (SNP) | VAF 101/203 reads (50%) | catalogued as rs767036448; called by muse, mutect2, varscan2
- EMILIN3 | c.333G>A p.K111= | Silent (SNP) | VAF 21/384 reads (5%) | called by muse, mutect2
- ENOX1 | c.528G>A p.K176= | Silent (SNP) | VAF 143/152 reads (94%) | catalogued as rs1429199878, COSV54923718, COSV99815593; called by muse, mutect2, varscan2
- EP400 | c.6123C>G p.V2041= | Silent (SNP) | VAF 546/727 reads (75%) | called by muse, mutect2, varscan2
- FN3K | c.60C>T p.P20= | Silent (SNP) | VAF 192/862 reads (22%) | catalogued as rs778789676; called by muse, mutect2, varscan2
- FOXJ3 | c.1002C>T p.P334= | Silent (SNP) | VAF 69/341 reads (20%) | catalogued as rs1276403512; called by muse, mutect2, varscan2
- GAP43 | c.75C>T p.I25= | Silent (SNP) | VAF 97/356 reads (27%) | called by muse, mutect2, varscan2
- GPR39 | c.411C>T p.I137= | Silent (SNP) | VAF 190/427 reads (44%) | called by muse, mutect2, varscan2
- GZMH | c.18C>T p.L6= | Silent (SNP) | VAF 113/232 reads (49%) | called by muse, mutect2, varscan2
- GZMM | c.225G>C p.L75= | Silent (SNP) | VAF 182/553 reads (33%) | catalogued as COSV52741773; called by muse, mutect2, varscan2
- HERC1 | c.12762G>A p.L4254= | Silent (SNP) | VAF 127/285 reads (45%) | called by muse, mutect2, varscan2
- HSPG2 | c.264G>A p.V88= | Silent (SNP) | VAF 124/245 reads (51%) | catalogued as rs1403049431; called by muse, mutect2, varscan2
- IL1RAPL1 | c.1443C>T p.Y481= | Silent (SNP) | VAF 210/211 reads (100%) | catalogued as rs777536426, COSV56293571; ClinVar: benign; called by muse, mutect2, varscan2
- IRF4 | c.36C>T p.F12= | Silent (SNP) | VAF 204/438 reads (47%) | catalogued as COSV66704496; called by muse, varscan2
- KCNH4 | c.1578C>T p.I526= | Silent (SNP) | VAF 119/245 reads (49%) | catalogued as rs1303724921, COSV52915277; called by muse, mutect2, varscan2
- KCNJ14 | c.30C>G p.L10= | Silent (SNP) | VAF 157/157 reads (100%) | catalogued as rs928639669, COSV53519720; called by muse, mutect2, varscan2
- LAMP2 | c.933C>T p.F311= | Silent (SNP) | VAF 98/371 reads (26%) | called by muse, mutect2, varscan2
- MAF | c.741C>T p.H247= | Silent (SNP) | VAF 74/169 reads (44%) | catalogued as rs751341494; called by muse, mutect2, varscan2
- MCAM | c.75C>G p.P25= | Silent (SNP) | VAF 110/280 reads (39%) | catalogued as rs779647125; called by muse, mutect2, varscan2
- MEN1 | c.1668C>G p.L556= | Silent (SNP) | VAF 228/536 reads (43%) | called by muse, mutect2, varscan2
- NOD2 | c.2226C>T p.L742= | Silent (SNP) | VAF 213/446 reads (48%) | catalogued as rs765131217, COSV100318445; called by muse, mutect2, varscan2
- NUP133 | c.1704G>A p.L568= | Silent (SNP) | VAF 95/370 reads (26%) | called by muse, mutect2, varscan2
- NUP98 | c.4854G>A p.E1618= (on ENST00000359171 / NM_001365126.1; = p.E1601= on NM_016320.5 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 96/296 reads (32%) | called by muse, mutect2, varscan2
- ODF1 | c.111C>T p.C37= | Silent (SNP) | VAF 140/320 reads (44%) | catalogued as rs144503717; called by muse, mutect2, varscan2
- OR13C2 | c.642C>A p.I214= | Silent (SNP) | VAF 129/255 reads (51%) | catalogued as COSV73377733; called by muse, mutect2, varscan2
- OSCP1 | c.1140C>T p.D380= (on ENST00000356637 / NM_001330493.1; = p.D370= on NM_145047.5) | Silent (SNP) | VAF 116/276 reads (42%) | catalogued as rs748276524, COSV52487938; called by muse, mutect2, varscan2
- PIP5K1C | c.1326G>C p.T442= | Silent (SNP) | VAF 278/278 reads (100%) | called by mutect2, varscan2
- QRICH1 | c.1014C>T p.N338= | Silent (SNP) | VAF 195/195 reads (100%) | catalogued as rs558954411, COSV62614559; called by muse, mutect2, varscan2
- SETX | c.4557C>G p.L1519= | Silent (SNP) | VAF 148/292 reads (51%) | called by muse, mutect2, varscan2
- SHCBP1L | c.1071C>T p.R357= | Silent (SNP) | VAF 127/225 reads (56%) | called by muse, mutect2, varscan2
- SMG6 | c.1225C>T p.L409= | Silent (SNP) | VAF 18/270 reads (7%) | called by muse, mutect2
- SOWAHA | c.951G>C p.R317= | Silent (SNP) | VAF 253/459 reads (55%) | called by muse, mutect2, varscan2
- SPACA9 | c.39G>A p.Q13= | Silent (SNP) | VAF 131/330 reads (40%) | called by muse, mutect2, varscan2
- STK31 | c.2853C>G p.L951= | Silent (SNP) | VAF 105/119 reads (88%) | catalogued as rs1232162107, COSV63459309; called by muse, mutect2, varscan2
- SYNE2 | c.19773G>A p.L6591= | Silent (SNP) | VAF 110/221 reads (50%) | called by muse, mutect2, varscan2
- TMEM123 | c.369G>A p.Q123= | Silent (SNP) | VAF 214/414 reads (52%) | called by muse, mutect2, varscan2
- TOM1L1 | c.726C>T p.L242= | Silent (SNP) | VAF 127/490 reads (26%) | called by muse, mutect2, varscan2
- UBN2 | c.1593C>G p.V531= | Silent (SNP) | VAF 46/329 reads (14%) | catalogued as COSV56035267; called by muse, mutect2, varscan2
- ZFP92 | c.837C>T p.L279= | Silent (SNP) | VAF 138/1314 reads (11%) | called by muse, mutect2
- ZNF688 | c.717G>A p.G239= | Silent (SNP) | VAF 226/500 reads (45%) | catalogued as rs528760504; called by muse, mutect2, varscan2
- ARRB2 | c.*99dup | 3'UTR (INS) | VAF 178/238 reads (75%) | called by mutect2, pindel, varscan2
- BTBD7 | c.1162+5324G>T | Intron (SNP) | VAF 158/539 reads (29%) | called by muse, mutect2, varscan2
- CKS1B | c.59+106G>A | Intron (SNP) | VAF 250/628 reads (40%) | catalogued as rs937451790, COSV58316909; called by muse, mutect2, varscan2
- COBL | c.1096+2091C>T | Intron (SNP) | VAF 137/138 reads (99%) | called by muse, mutect2, varscan2
- CPLANE1 | c.*5938C>T | 3'UTR (SNP) | VAF 100/362 reads (28%) | called by muse, mutect2, varscan2
- DST | c.4297-3537G>A | Intron (SNP) | VAF 126/287 reads (44%) | catalogued as rs1390801517, COSV55044002; called by muse, mutect2, varscan2
- KCNQ1 | c.1393+22222T>G | Intron (SNP) | VAF 137/203 reads (67%) | called by muse, mutect2, varscan2
- MYO18B | chr22:26030948 C>A | 3'Flank (SNP) | VAF 48/276 reads (17%) | called by mutect2, varscan2
- NRSN1 | c.190-4383C>A | Intron (SNP) | VAF 71/138 reads (51%) | called by muse, mutect2, varscan2
- PCID2 | c.36+554G>A | Intron (SNP) | VAF 125/125 reads (100%) | called by muse, mutect2, varscan2
- SLC35E2A | n.1071G>A | RNA (SNP) | VAF 94/454 reads (21%) | called by muse, mutect2, varscan2
- TMEM8B | c.-721C>T | 5'UTR (SNP) | VAF 154/313 reads (49%) | called by muse, mutect2, varscan2
- USP46 | c.*4786C>G | 3'UTR (SNP) | VAF 116/131 reads (89%) | called by muse, mutect2, varscan2
